Gene-level copy-number profile of tumor specimen TCGA-BR-8370-01A from TCGA case TCGA-BR-8370, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 64.7 years (23,636 days).
Specimen TCGA-BR-8370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.03ccbe2f-2274-4cb6-8e22-bce1e523c520.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8370-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7c7660f-82c3-48e6-bd0d-6702427c1c92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,923; copy number 2: 44,710; copy number 3: 12,181.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8370-01A-11D-2338-01): tumor purity 0.96, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 819. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
